Somatic mutation profile of tumor specimen 0DTMFO from CCDI case PBCJXX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 10.5 years (3,843 days).
Specimen 0DTMFO: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6ddc61a5-c567-44f5-9dca-9889414a7d0f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DTMFP (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/100af9df-f2a3-4be1-9328-280fbc2c13bd

The open-access MAF lists 33 somatic variants for this specimen: 23 protein-altering or splice-affecting, 3 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Intron 4, Silent 3, Frame Shift Ins 2, 5'UTR 2, Nonsense Mutation 2, 3'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.101G>A p.G34E | Missense Mutation (SNP) | VAF 196/428 reads (46%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs28931589, COSV62687976, COSV62688267, COSV62692205; ClinVar: likely pathogenic /  other / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 70/348 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ARID2 | c.2474C>A p.S825* | Nonsense Mutation (SNP) | VAF 115/266 reads (43%) | catalogued as COSV57594865; called by muse, mutect2, varscan2
- FEM1C | c.983G>A p.R328H | Missense Mutation (SNP) | VAF 47/344 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778476474, COSV57231571; called by muse, mutect2, varscan2
- GCDH | c.121G>T p.A41S | Missense Mutation (SNP) | VAF 66/412 reads (16%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.003); catalogued as COSV99322447, COSV99322552; called by muse, mutect2, varscan2
- LRRC31 | c.1624dup p.R542Kfs*6 | Frame Shift Ins (INS) | VAF 109/354 reads (31%) | catalogued as COSV99246562; called by mutect2, varscan2
- PIP4P1 | c.566G>A p.R189H | Missense Mutation (SNP) | VAF 84/223 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); catalogued as rs776716699, COSV51657593; called by muse, mutect2, varscan2
- RBMXL3 | c.718C>T p.R240W | Missense Mutation (SNP) | VAF 87/767 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.72); catalogued as rs782610346; called by muse, mutect2, varscan2
- SLC35A3 | c.73C>T p.R25C | Missense Mutation (SNP) | VAF 220/506 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753997682, COSV64516037; called by muse, mutect2, varscan2
- SMARCB1 | c.928_929del p.L310Dfs*4 (on ENST00000263121; = p.L356Dfs*4 on NM_003073.5) | Frame Shift Del (DEL) | VAF 168/492 reads (34%) | catalogued as rs1555881563; called by pindel, varscan2
- UPF1 | c.1807G>A p.E603K (on ENST00000599848 / NM_001297549.2; = p.E592K on NM_002911.4) | Missense Mutation (SNP) | VAF 37/256 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.464); catalogued as COSV53202131; called by muse, mutect2, varscan2
- ZMYM3 | c.944G>A p.R315Q | Missense Mutation (SNP) | VAF 193/431 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.349); catalogued as rs1400987270; called by muse, mutect2, varscan2
- ZNF292 | c.2185C>T p.R729W | Missense Mutation (SNP) | VAF 208/231 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60546480; called by muse, mutect2, varscan2
- ATM | c.2604T>A p.D868E | Missense Mutation (SNP) | VAF 88/336 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CDKN1C | c.273C>A p.Y91* | Nonsense Mutation (SNP) | VAF 68/448 reads (15%) | called by muse, mutect2, varscan2
- CMTM1 | c.481G>A p.G161S (on ENST00000457188 / NM_181269.3; = p.G278S on NM_052999.4) | Missense Mutation (SNP) | VAF 57/484 reads (12%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CSMD1 | c.7624G>T p.G2542W (on ENST00000520002; = p.G2541W on NM_033225.6) | Missense Mutation (SNP) | VAF 44/359 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FOXO3 | c.233_237dup p.G80Rfs*42 | Frame Shift Ins (INS) | VAF 39/171 reads (23%) | called by mutect2, pindel, varscan2
- GRIN2B | c.511A>G p.I171V | Missense Mutation (SNP) | VAF 77/583 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- KIR3DL2 | c.954C>A p.N318K | Missense Mutation (SNP) | VAF 34/476 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.628); called by muse, mutect2
- PIK3C2G | c.3811A>C p.N1271H (on ENST00000676171; = p.N1230H on NM_004570.5) | Missense Mutation (SNP) | VAF 132/317 reads (42%) | SIFT tolerated (0.39); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SCYL3 | c.1545C>A p.D515E (on ENST00000367770; = p.D461E on NM_020423.7) | Missense Mutation (SNP) | VAF 68/463 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TENM1 | c.7746G>T p.E2582D | Missense Mutation (SNP) | VAF 49/366 reads (13%) | SIFT tolerated (0.57); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- GYPA | c.402C>T p.D134= | Silent (SNP) | VAF 171/387 reads (44%) | catalogued as rs757151303; called by muse, mutect2, varscan2
- PCDHB3 | c.1815G>A p.Q605= | Silent (SNP) | VAF 24/96 reads (25%) | catalogued as rs1554272572; called by muse, mutect2
- TMEM178A | c.184C>T p.L62= | Silent (SNP) | VAF 34/374 reads (9%) | catalogued as rs1243419392, COSV56141823; called by muse, mutect2
- CTSC | c.318+8573C>A | Intron (SNP) | VAF 69/243 reads (28%) | catalogued as rs375478636; called by muse, mutect2, varscan2
- DDX5 | c.45-9dup | Intron (INS) | VAF 54/228 reads (24%) | catalogued as rs199960115; called by mutect2, varscan2
- HDAC6 | c.1994+41C>T | Intron (SNP) | VAF 201/414 reads (49%) | catalogued as rs1329610719; called by muse, mutect2, varscan2
- SLC52A2 | c.130+38T>C | Intron (SNP) | VAF 82/272 reads (30%) | called by muse, mutect2, varscan2
- SPATA5L1 | c.-56T>C | 5'UTR (SNP) | VAF 26/328 reads (8%) | catalogued as rs953559668; called by muse, mutect2
- WFDC9 | c.*13G>A | 3'UTR (SNP) | VAF 114/308 reads (37%) | catalogued as rs770081846, COSV100385746; called by muse, mutect2, varscan2
- ZNF595 | c.-20G>A | 5'UTR (SNP) | VAF 37/438 reads (8%) | catalogued as rs751893161, COSV59553092; called by muse, mutect2
